Somatic mutation profile of tumor specimen C3L-00568-01 (aliquot CPT0023470005) from CPTAC case C3L-00568, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 74.7 years (27,278 days).
Specimen C3L-00568-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0f727b4-124c-4e4a-bc63-0f484d21bbe5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00568-31 (Blood Derived Normal), aliquot CPT0024570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e53883d-e829-4af2-907b-180f42764794

The open-access MAF lists 344 somatic variants for this specimen: 242 protein-altering or splice-affecting, 64 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 213, Silent 64, Nonsense Mutation 16, Intron 15, RNA 9, 5'UTR 7, Frame Shift Del 6, 5'Flank 4, Splice Site 3, Splice Region 3, 3'UTR 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 90/770 reads (12%) | catalogued as rs786201592, COSV52735606, COSV52751148, COSV52783951; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 94/792 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- USH2A | c.9676C>T p.R3226* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as rs760858249, CM149209, COSV56348686; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs1368246283; called by muse, mutect2, varscan2
- ACSM4 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV68069413; called by muse, mutect2, varscan2
- AGO4 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs753154575; called by mutect2, varscan2
- ALDH1B1 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 53/411 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as rs147930374, COSV66619331; called by muse, mutect2, varscan2
- APOA4 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 22/846 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1462357756, COSV100759242; called by muse, mutect2
- ASPM | c.9593G>A p.R3198H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as rs145333987, COSV54127999; called by muse, mutect2, varscan2
- ATP13A4 | c.2966G>C p.G989A | Missense Mutation (SNP) | VAF 36/437 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.085); catalogued as rs752143332; called by muse, mutect2
- BMP5 | c.844A>T p.N282Y | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV63700913; called by muse, mutect2, varscan2
- BRINP3 | c.1885C>G p.L629V | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV66517530; called by muse, mutect2, varscan2
- CCDC40 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 34/1016 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100884331, COSV66472804; called by muse, mutect2
- CD1B | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63804561; called by muse, mutect2
- CDR1 | c.381G>T p.M127I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV65163917; called by muse, mutect2
- COG7 | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs755090097; called by muse, mutect2
- COL11A1 | c.2284del p.R762Gfs*3 | Frame Shift Del (DEL) | VAF 26/247 reads (11%) | catalogued as COSV62175625; called by mutect2, pindel
- CREB3L3 | c.50T>C p.M17T | Missense Mutation (SNP) | VAF 148/1089 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1382817467; called by muse, mutect2, varscan2
- CSF2RB | c.624C>A p.Y208* | Nonsense Mutation (SNP) | VAF 108/893 reads (12%) | catalogued as rs763038738; called by muse, mutect2, varscan2
- CSKMT | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs1335376097; called by muse, mutect2, varscan2
- DCHS1 | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 84/545 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55033657; called by muse, mutect2, varscan2
- DDI2 | c.958A>G p.M320V | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1056577268; called by muse, mutect2
- DDX27 | c.2099C>G p.S700C | Missense Mutation (SNP) | VAF 15/384 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV100872196; called by muse, mutect2
- DSEL | c.2013G>T p.W671C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59490691; called by muse, mutect2, varscan2
- ELF4 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 90/845 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV57451686; called by muse, mutect2, varscan2
- EXOC7 | c.484A>T p.S162C | Missense Mutation (SNP) | VAF 23/668 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58741108; called by muse, mutect2
- F7 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV60646904; called by muse, mutect2
- FRMPD4 | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs772365939, COSV66210829; called by muse, mutect2, varscan2
- GLRB | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.899); catalogued as rs776194537; called by muse, mutect2, varscan2
- GPR152 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 18/498 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV56888102; called by muse, mutect2
- GTF3C1 | c.2636A>G p.Y879C | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs748532438; called by muse, varscan2
- H4C6 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs1201414781; called by muse, mutect2, varscan2
- HK3 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 63/472 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.023); catalogued as rs150272942; called by muse, varscan2
- HMCN1 | c.5062A>T p.I1688F | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV99629166; called by muse, mutect2, varscan2
- HRNR | c.3115C>A p.P1039T | Missense Mutation (SNP) | VAF 153/1545 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs201853812; called by muse, varscan2
- IDE | c.2035C>T p.H679Y | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769934676; called by muse, mutect2, varscan2
- KCNK9 | c.1062C>G p.I354M | Missense Mutation (SNP) | VAF 26/924 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as COSV57278799, COSV57284405; called by muse, mutect2
- KCNU1 | c.2003C>A p.T668N | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV67758100; called by muse, mutect2, varscan2
- KEAP1 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 69/527 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV50268536, COSV50673043; called by muse, mutect2, varscan2
- KIAA1755 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs774092490, COSV54080653; called by muse, mutect2, varscan2
- KMT2D | c.15472G>C p.E5158Q | Missense Mutation (SNP) | VAF 28/908 reads (3%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.609); catalogued as COSV56409041; called by muse, mutect2
- L1CAM | c.719C>A p.P240Q | Missense Mutation (SNP) | VAF 99/809 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960915; called by muse, mutect2, varscan2
- LCOR | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 187/898 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.795); catalogued as rs1326035136; called by muse, mutect2, varscan2
- LSM14A | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV70885031; called by muse, varscan2
- MAP3K10 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV53420233; called by muse, mutect2, varscan2
- MIA2 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as COSV54481923; called by muse, mutect2
- MLLT1 | c.755A>G p.K252R | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs559328074; called by muse, mutect2
- MORC4 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs868172752, COSV99717292; called by muse, mutect2, varscan2
- MPLKIP | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 59/458 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.824); catalogued as rs565833937, COSV59312257; called by muse, mutect2, varscan2
- MRTFA | c.1142A>G p.Q381R | Missense Mutation (SNP) | VAF 77/463 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1250785126; called by mutect2, varscan2
- MYH15 | c.5622C>A p.S1874R | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.718); catalogued as rs1265376001; called by muse, mutect2, varscan2
- MYH4 | c.4157G>C p.R1386P | Missense Mutation (SNP) | VAF 49/513 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55113478; called by muse, mutect2
- NELL2 | c.578A>G p.Q193R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61573356; called by muse, mutect2, varscan2
- NIBAN2 | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.123); catalogued as rs1331767928, COSV55938219; called by muse, mutect2, varscan2
- NPR1 | c.1988C>A p.S663* | Nonsense Mutation (SNP) | VAF 34/330 reads (10%) | catalogued as COSV64117832; called by muse, mutect2, varscan2
- NRXN3 | c.2782A>G p.I928V (on ENST00000335750 / NM_001330195.2; = p.I555V on NM_004796.6) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); catalogued as rs761698904; called by mutect2, varscan2
- NTN4 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.186); catalogued as rs267603725; called by mutect2, varscan2
- OPHN1 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100830454; called by muse, mutect2
- OR2G3 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV100180466, COSV60681720; called by muse, mutect2, varscan2
- OR52K1 | c.219G>T p.L73F | Missense Mutation (SNP) | VAF 61/350 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100297672; called by muse, mutect2, varscan2
- OR9I1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56925175; called by muse, mutect2, varscan2
- PCDHA12 | c.1678G>C p.D560H | Missense Mutation (SNP) | VAF 88/1326 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs370292278, COSV56489279; called by muse, mutect2
- PCDHA8 | c.2115C>G p.C705W | Missense Mutation (SNP) | VAF 130/844 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs781786542, COSV65333833; called by muse, mutect2, varscan2
- PGP | c.892G>C p.V298L | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV57026844; called by muse, varscan2
- PIWIL3 | c.1163C>A p.T388K | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.055); catalogued as COSV59995336; called by muse, mutect2, varscan2
- PLCL2 | c.664T>C p.Y222H (on ENST00000615277 / NM_001144382.2; = p.Y96H on NM_015184.5) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs745955226; called by muse, mutect2, varscan2
- PLEKHG7 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 17/469 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV67337825; called by muse, mutect2
- PNPLA3 | c.547A>T p.T183S | Missense Mutation (SNP) | VAF 70/416 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs1428853172; called by muse, mutect2, varscan2
- PRDM16 | c.1259G>T p.R420L | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752753184, COSV54585853; called by muse, mutect2, varscan2
- RIMS2 | c.2860A>G p.S954G (on ENST00000666250 / NM_001348490.2; = p.S762G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as rs1409088068; called by muse, mutect2, varscan2
- RNF17 | c.2687A>G p.N896S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1408300945; called by mutect2, varscan2
- RYR3 | c.9685G>A p.V3229M (on ENST00000389232; = p.V3230M on NM_001036.6) | Missense Mutation (SNP) | VAF 105/812 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs1486456045; called by muse, mutect2, varscan2
- SHPK | c.997A>G p.M333V | Missense Mutation (SNP) | VAF 48/469 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs1291137091; called by muse, mutect2
- SNRPN | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 28/293 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs758956901; called by muse, mutect2, varscan2
- SUPT20HL2 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 62/436 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs769016710; called by muse, mutect2, varscan2
- TASOR2 | c.5786C>T p.S1929F | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs745811940, COSV60166614; called by muse, mutect2
- TNS3 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60792868; called by muse, mutect2, varscan2
- TRMT2B | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV100105779; called by muse, mutect2, varscan2
- TSHZ2 | c.2441C>T p.S814F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100296168; called by muse, varscan2
- UBAP1L | c.53G>C p.G18A | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV72399580; called by muse, mutect2
- VPS35L | c.2039G>C p.R680P | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV51985433; called by mutect2, varscan2
- ZEB2 | c.2362C>G p.L788V | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV57954739; called by muse, mutect2, varscan2
- ZNF205 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758186740, COSV54621823; called by muse, mutect2
- ABCC13 | n.276C>G | Splice Region (SNP) | VAF 28/228 reads (12%) | called by muse, mutect2, varscan2
- AC004922.1 | c.817A>T p.N273Y | Missense Mutation (SNP) | VAF 91/576 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- AC006059.2 | c.2057G>A p.R686K | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ADCY10 | c.3553C>T p.H1185Y | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ALK | c.86_87del p.A29Gfs*28 | Frame Shift Del (DEL) | VAF 34/246 reads (14%) | called by pindel, varscan2
- ANP32E | c.123C>G p.F41L | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- AP1G1 | c.2344A>C p.I782L | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.019); called by muse, varscan2
- APBB2 | c.1317T>G p.S439R (on ENST00000295974 / NM_001166050.2; = p.S440R on NM_004307.2) | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP33 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); called by muse, mutect2
- ATP11B | c.1593A>T p.E531D | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AUTS2 | c.1571dup p.H525Pfs*41 | Frame Shift Ins (INS) | VAF 85/778 reads (11%) | called by mutect2, pindel, varscan2
- BACH1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- BCAN | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C19orf44 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 98/773 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- C19orf44 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CACNA1G | c.3379G>C p.E1127Q | Missense Mutation (SNP) | VAF 20/677 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CADM4 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CALU | c.97C>G p.Q33E | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- CDH10 | c.1214C>G p.T405S | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CDH8 | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- CDHR2 | c.2646C>G p.I882M | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CFAP47 | c.8752C>A p.L2918M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- CKAP5 | c.433A>T p.I145L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCN5 | c.1469G>T p.C490F | Missense Mutation (SNP) | VAF 67/468 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- CLIP2 | c.1913G>T p.G638V | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- COL4A3 | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COL4A5 | c.1151T>A p.L384H | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.428); called by muse, varscan2
- COL6A1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CPAMD8 | c.81G>T p.W27C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- CPEB1 | c.1393G>T p.E465* (on ENST00000617958; = p.E400* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- CTNND2 | c.2573C>G p.S858* | Nonsense Mutation (SNP) | VAF 39/414 reads (9%) | called by muse, mutect2
- CUBN | c.123-2A>T p.X41_splice | Splice Site (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- CWC25 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CYP4F11 | c.55T>C p.W19R | Missense Mutation (SNP) | VAF 13/271 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- DCAF4L2 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 60/592 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DGKK | c.2504T>C p.L835P | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DHX34 | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DIP2A | c.4636G>C p.G1546R | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNAP | c.364T>A p.C122S (on ENST00000321600; = p.C96S on NM_173629.3) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- EIF4A2 | c.772-22_774del p.X258_splice | Splice Site (DEL) | VAF 25/97 reads (26%) | called by mutect2, pindel
- ELOVL2 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EPB41L2 | c.1084C>A p.Q362K | Missense Mutation (SNP) | VAF 46/361 reads (13%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPX | c.716C>A p.P239Q | Missense Mutation (SNP) | VAF 90/787 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ERAP1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- F2 | c.1461G>C p.E487D | Missense Mutation (SNP) | VAF 50/355 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- FADS2 | c.1064G>A p.W355* | Nonsense Mutation (SNP) | VAF 34/284 reads (12%) | called by muse, mutect2, varscan2
- FIG4 | c.1704A>T p.K568N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FOXK1 | c.354_363del p.M118Ifs*16 | Frame Shift Del (DEL) | VAF 41/300 reads (14%) | called by mutect2, pindel, varscan2
- GALR2 | c.1009C>A p.R337S | Missense Mutation (SNP) | VAF 54/396 reads (14%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GDPD2 | c.354C>A p.S118R | Missense Mutation (SNP) | VAF 37/546 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- GDPD2 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 36/542 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.02); called by muse, mutect2
- GRB14 | c.1402A>T p.S468C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GRK1 | c.170A>C p.E57A | Missense Mutation (SNP) | VAF 26/776 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- H2BC11 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 87/737 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- HCN2 | c.2618G>A p.G873D | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HDAC10 | c.1931T>C p.V644A | Missense Mutation (SNP) | VAF 15/417 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- HMCES | c.938A>T p.Q313L | Missense Mutation (SNP) | VAF 36/624 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2
- HMCN2 | c.179C>A p.S60* | Nonsense Mutation (SNP) | VAF 17/510 reads (3%) | called by muse, mutect2
- HRNR | c.3116C>T p.P1039L | Missense Mutation (SNP) | VAF 156/1566 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.033); called by muse, varscan2
- HSPG2 | c.13103C>G p.A4368G | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- HUS1B | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 74/862 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.25); called by muse, mutect2
- INTS6 | c.1963A>G p.K655E | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- IP6K2 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQCG | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.446); called by muse, mutect2
- ITPKA | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 46/358 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ITPKB | c.1279C>G p.R427G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH1 | c.892A>T p.I298F | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KHDRBS3 | c.391A>C p.I131L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- KIAA1755 | c.506C>A p.S169* | Nonsense Mutation (SNP) | VAF 28/597 reads (5%) | called by muse, mutect2
- KMT2B | c.1656del p.K553Nfs*52 | Frame Shift Del (DEL) | VAF 50/318 reads (16%) | called by mutect2, pindel, varscan2
- KMT2D | c.4168del p.A1390Qfs*27 | Frame Shift Del (DEL) | VAF 24/214 reads (11%) | called by mutect2, pindel
- KRTAP10-11 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 148/996 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, varscan2
- LEMD2 | c.890G>T p.S297I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC7 | c.2437G>A p.D813N (on ENST00000651989 / NM_001370785.2; = p.D780N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/275 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- MARCHF4 | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 54/358 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MMEL1 | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MOV10 | c.2762A>G p.N921S | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MPEG1 | c.738C>G p.N246K | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MROH2A | c.1258A>G p.R420G | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MUC5B | c.13522C>G p.P4508A | Missense Mutation (SNP) | VAF 207/1268 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- MUTYH | c.245A>T p.H82L | Missense Mutation (SNP) | VAF 67/573 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- MYBPC2 | c.1358C>G p.S453* | Nonsense Mutation (SNP) | VAF 15/472 reads (3%) | called by muse, mutect2
- MYH7 | c.4332G>C p.K1444N | Missense Mutation (SNP) | VAF 13/456 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NALCN | c.2513T>G p.F838C | Missense Mutation (SNP) | VAF 14/448 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NDN | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2
- NLRP13 | c.1592G>T p.C531F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- NOS1 | c.1339A>T p.I447F | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NOS1 | c.714C>G p.I238M | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.245); called by muse, mutect2
- NRK | c.1418G>A p.R473K | Missense Mutation (SNP) | VAF 64/470 reads (14%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- OPHN1 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 30/389 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- OR1L4 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- OR4C6 | c.723C>A p.H241Q | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52K1 | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 60/350 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- PAK3 | c.1507C>A p.L503M (on ENST00000262836 / NM_001324328.2; = p.L488M on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2
- PCDHGC3 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 32/588 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- PGBD5 | c.1068A>T p.G356= (on ENST00000525115; = p.G425= on NM_001258311.2) | Splice Region (SNP) | VAF 24/212 reads (11%) | called by muse, mutect2, varscan2
- PIKFYVE | c.3647A>G p.Q1216R | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PJA1 | c.1888G>C p.G630R (on ENST00000361478 / NM_145119.4; = p.G442R on NM_022368.5) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLP1 | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 81/683 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PLPBP | c.426G>T p.M142I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- POMGNT2 | c.731A>T p.Q244L | Missense Mutation (SNP) | VAF 62/431 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRDM14 | c.388G>C p.G130R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); called by mutect2, varscan2
- PRICKLE1 | c.1329G>T p.W443C | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- PRKACB | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- PRR5L | c.192C>G p.F64L | Missense Mutation (SNP) | VAF 8/252 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2
- PSKH2 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 74/696 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PTER | c.350C>G p.T117S | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.51); called by muse, mutect2
- PTGIS | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 12/380 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); called by muse, mutect2
- PTPN5 | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 18/598 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.297); called by muse, mutect2
- PTPRB | c.156G>T p.W52C | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRN2 | c.2908A>G p.K970E | Missense Mutation (SNP) | VAF 45/387 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PTPRZ1 | c.683A>T p.Y228F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RINT1 | c.664A>G p.K222E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- RNF115 | c.845A>T p.Q282L | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RNF125 | c.142G>T p.V48F | Missense Mutation (SNP) | VAF 64/585 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- RPH3A | c.990G>T p.E330D (on ENST00000389385 / NM_001143854.2; = p.E326D on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPH3A | c.991G>T p.E331* (on ENST00000389385 / NM_001143854.2; = p.E327* on NM_014954.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/263 reads (12%) | called by muse, mutect2, varscan2
- RPL27A | c.255G>C p.Q85H | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2
- RPL41 | c.32G>C p.R11P | Missense Mutation (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- SCN11A | c.65A>G p.D22G | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- SCNM1 | c.309+1G>A p.X103_splice | Splice Site (SNP) | VAF 35/181 reads (19%) | called by muse, mutect2, varscan2
- SDK2 | c.5777T>A p.F1926Y | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- SEC31B | c.2435C>T p.T812I | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- SHANK2 | c.1691G>C p.W564S | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, varscan2
- SIGLEC8 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, varscan2
- SLC2A13 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 28/232 reads (12%) | called by muse, mutect2, varscan2
- SLC33A1 | c.1391C>G p.S464C | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- SORCS1 | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2
- SORCS3 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.426); called by muse, varscan2
- SPATA31A6 | c.3642C>G p.D1214E | Missense Mutation (SNP) | VAF 119/928 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTBN4 | c.6815C>T p.S2272L | Missense Mutation (SNP) | VAF 384/972 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAB2 | c.4661C>T p.T1554I | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- SZT2 | c.4462G>A p.E1488K (on ENST00000634258 / NM_001365999.1; = p.E1431K on NM_015284.4) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TCEAL6 | c.341C>A p.T114K | Missense Mutation (SNP) | VAF 42/358 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TENM1 | c.4086G>A p.V1362= | Splice Region (SNP) | VAF 19/145 reads (13%) | called by mutect2, varscan2
- TKTL2 | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMC2 | c.1489C>A p.H497N | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TMEM132D | c.2630A>T p.H877L | Missense Mutation (SNP) | VAF 61/476 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM138 | c.425del p.G142Afs*27 | Frame Shift Del (DEL) | VAF 31/294 reads (11%) | called by mutect2, pindel, varscan2
- TP53RK | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2
- TRAK2 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TRIM51 | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRPC5 | c.1043A>G p.Y348C | Missense Mutation (SNP) | VAF 53/414 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TTN | c.58946C>T p.P19649L (on ENST00000591111; = p.P12225L on NM_003319.4) | Missense Mutation (SNP) | VAF 54/552 reads (10%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TUFM | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 30/894 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- TULP4 | c.3732C>A p.Y1244* | Nonsense Mutation (SNP) | VAF 28/316 reads (9%) | called by muse, mutect2
- UBTFL1 | c.827T>A p.L276Q | Missense Mutation (SNP) | VAF 48/418 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- UNC13A | c.218C>A p.T73K | Missense Mutation (SNP) | VAF 51/373 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VWF | c.3710G>A p.C1237Y | Missense Mutation (SNP) | VAF 114/986 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XKR5 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 45/478 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.214); called by muse, mutect2
- ZFAND4 | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ZFHX4 | c.3674A>G p.N1225S | Missense Mutation (SNP) | VAF 59/415 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFHX4 | c.7421C>G p.P2474R | Missense Mutation (SNP) | VAF 50/381 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF281 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF425 | c.1247G>T p.C416F | Missense Mutation (SNP) | VAF 29/293 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF431 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ZNF605 | c.1002G>T p.K334N | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNRF2 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- ZRANB3 | c.2792G>A p.W931* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- AGMO | c.1290C>T p.F430= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs1212493704, COSV61110089; called by muse, mutect2, varscan2
- ASL | c.498C>T p.P166= | Silent (SNP) | VAF 76/602 reads (13%) | catalogued as rs1293664442; called by muse, mutect2, varscan2
- ATP1A4 | c.294C>T p.V98= | Silent (SNP) | VAF 35/338 reads (10%) | called by muse, mutect2
- BCORL1 | c.615C>A p.P205= | Silent (SNP) | VAF 39/205 reads (19%) | called by muse, mutect2, varscan2
- CALR3 | c.45A>T p.R15= | Silent (SNP) | VAF 89/680 reads (13%) | called by muse, mutect2, varscan2
- CCDC168 | c.13524A>T p.T4508= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- CNOT2 | c.24A>G p.T8= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs1264004070; called by muse, mutect2
- CRNN | c.519C>A p.S173= | Silent (SNP) | VAF 38/286 reads (13%) | catalogued as COSV55121391; called by muse, mutect2, varscan2
- CYP7B1 | c.1218C>A p.I406= | Silent (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2
- DCAF12L2 | c.33G>A p.R11= | Silent (SNP) | VAF 72/715 reads (10%) | called by muse, mutect2, varscan2
- DHDH | c.720G>A p.V240= | Silent (SNP) | VAF 27/196 reads (14%) | catalogued as COSV99668615; called by muse, mutect2, varscan2
- DMRTC2 | c.108C>T p.I36= | Silent (SNP) | VAF 13/283 reads (5%) | called by muse, mutect2
- DNAI4 | c.1908G>A p.K636= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- DNAJB5 | c.438C>T p.F146= | Silent (SNP) | VAF 34/722 reads (5%) | called by muse, mutect2
- EMILIN2 | c.969C>T p.D323= | Silent (SNP) | VAF 54/443 reads (12%) | catalogued as rs773075532, COSV99599080; called by muse, mutect2, varscan2
- EVC2 | c.2052G>A p.R684= | Silent (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- FAS | c.558A>G p.L186= | Silent (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- FASN | c.1716G>A p.L572= | Silent (SNP) | VAF 29/515 reads (6%) | called by muse, mutect2
- FRMD1 | c.1167C>A p.S389= | Silent (SNP) | VAF 71/716 reads (10%) | catalogued as COSV99349381; called by muse, mutect2
- FUT9 | c.294A>G p.S98= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- GK2 | c.1440A>T p.S480= | Silent (SNP) | VAF 27/183 reads (15%) | called by muse, mutect2, varscan2
- HPSE2 | c.387G>A p.R129= | Silent (SNP) | VAF 132/614 reads (21%) | called by muse, mutect2, varscan2
- HR | c.1164G>A p.S388= | Silent (SNP) | VAF 109/941 reads (12%) | catalogued as rs143466437; called by muse, mutect2, varscan2
- HSPA9 | c.69C>T p.A23= | Silent (SNP) | VAF 79/490 reads (16%) | catalogued as rs905791511, COSV51865681; called by muse, mutect2, varscan2
- IGSF3 | c.3540C>T p.C1180= (on ENST00000369486 / NM_001007237.3; = p.C1200= on NM_001542.4) | Silent (SNP) | VAF 44/387 reads (11%) | catalogued as rs1451363599; called by muse, mutect2, varscan2
- ISL1 | c.273C>T p.F91= | Silent (SNP) | VAF 21/645 reads (3%) | catalogued as COSV100045607, COSV57933430; called by muse, mutect2
- ITPR1 | c.6969C>T p.I2323= (on ENST00000354582; = p.I2268= on NM_002222.7) | Silent (SNP) | VAF 77/574 reads (13%) | catalogued as rs369778265; ClinVar: benign; called by muse, mutect2, varscan2
- KANK4 | c.663A>C p.S221= | Silent (SNP) | VAF 42/333 reads (13%) | called by muse, mutect2, varscan2
- KCNK13 | c.810C>T p.C270= | Silent (SNP) | VAF 17/552 reads (3%) | called by muse, mutect2
- KHK | c.411C>T p.H137= | Silent (SNP) | VAF 46/550 reads (8%) | catalogued as COSV53150621; called by muse, mutect2
- MAGEL2 | c.354G>A p.P118= | Silent (SNP) | VAF 65/483 reads (13%) | catalogued as rs1464719598, COSV58566157; called by muse, mutect2, varscan2
- MINK1 | c.2946C>T p.L982= | Silent (SNP) | VAF 46/353 reads (13%) | catalogued as rs370114801, COSV53419552; called by muse, mutect2, varscan2
- MS4A14 | c.1311C>A p.P437= | Silent (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
- MYO15B | c.4074G>A p.Q1358= | Silent (SNP) | VAF 62/435 reads (14%) | called by muse, mutect2, varscan2
- MYO16 | c.3919C>A p.R1307= | Silent (SNP) | VAF 67/566 reads (12%) | catalogued as COSV100697146, COSV100697218; called by muse, mutect2, varscan2
- NIPBL | c.8352G>C p.L2784= | Silent (SNP) | VAF 24/206 reads (12%) | catalogued as COSV56953519; called by muse, mutect2, varscan2
- OR10S1 | c.363G>A p.L121= | Silent (SNP) | VAF 64/412 reads (16%) | catalogued as rs867980308; called by muse, mutect2, varscan2
- OR2T33 | c.510C>T p.H170= | Silent (SNP) | VAF 106/712 reads (15%) | catalogued as rs759126664; called by muse, varscan2
- OR51G2 | c.726C>A p.A242= | Silent (SNP) | VAF 34/247 reads (14%) | called by muse, mutect2, varscan2
- PAX3 | c.12G>T p.L4= | Silent (SNP) | VAF 69/547 reads (13%) | catalogued as rs747090056; called by muse, mutect2, varscan2
- PAX6 | c.861C>T p.I287= | Silent (SNP) | VAF 66/455 reads (15%) | catalogued as rs754125688; called by muse, mutect2, varscan2
- PCDHA7 | c.1353C>T p.N451= | Silent (SNP) | VAF 112/817 reads (14%) | catalogued as rs781957990, COSV65343883; called by muse, mutect2, varscan2
- PCDHB15 | c.1953G>T p.P651= | Silent (SNP) | VAF 49/1001 reads (5%) | catalogued as rs782098059; called by muse, mutect2
- PCDHB2 | c.1074C>T p.I358= | Silent (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- PCDHGA7 | c.2139G>T p.A713= | Silent (SNP) | VAF 84/600 reads (14%) | called by muse, mutect2, varscan2
- PKD1 | c.4182C>T p.L1394= | Silent (SNP) | VAF 103/784 reads (13%) | catalogued as rs758685227, COSV99237302; called by muse, mutect2, varscan2
- PRDM14 | c.387G>T p.L129= | Silent (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- PSD2 | c.1062C>T p.F354= | Silent (SNP) | VAF 26/418 reads (6%) | catalogued as rs774410580, COSV51205820; called by muse, mutect2
- PTPN22 | c.513C>A p.I171= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- RANBP17 | c.1455C>T p.I485= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- RBMXL3 | c.2001C>G p.G667= | Silent (SNP) | VAF 96/1030 reads (9%) | called by muse, mutect2
- SCLY | c.582G>A p.P194= (on ENST00000651534; = p.P186= on NM_016510.7) | Silent (SNP) | VAF 45/404 reads (11%) | catalogued as rs753789578; called by muse, mutect2, varscan2
- SLC25A34 | c.801C>G p.L267= | Silent (SNP) | VAF 36/296 reads (12%) | called by muse, mutect2, varscan2
- SLC7A10 | c.861C>T p.Y287= | Silent (SNP) | VAF 58/832 reads (7%) | called by muse, mutect2
- THBS2 | c.141G>C p.G47= | Silent (SNP) | VAF 16/276 reads (6%) | catalogued as COSV64678387; called by muse, mutect2
- TMC4 | c.1344C>G p.L448= (on ENST00000617472 / NM_001145303.3; = p.L442= on NM_144686.4) | Silent (SNP) | VAF 46/457 reads (10%) | called by muse, mutect2, varscan2
- TRPC7 | c.741C>T p.N247= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100726000; called by muse, mutect2
- TRPV5 | c.568A>C p.R190= | Silent (SNP) | VAF 65/500 reads (13%) | catalogued as rs369558063; called by muse, mutect2, varscan2
- TUBGCP6 | c.1188G>T p.L396= | Silent (SNP) | VAF 65/494 reads (13%) | called by muse, mutect2, varscan2
- WDR27 | c.1068A>C p.S356= | Silent (SNP) | VAF 30/271 reads (11%) | called by muse, mutect2
- WDR87 | c.651C>G p.L217= | Silent (SNP) | VAF 47/446 reads (11%) | called by muse, mutect2, varscan2
- ZCCHC3 | c.735G>A p.L245= | Silent (SNP) | VAF 23/626 reads (4%) | called by muse, mutect2
- ZNF497 | c.1041G>A p.E347= | Silent (SNP) | VAF 33/248 reads (13%) | catalogued as rs761309097; called by muse, mutect2, varscan2
- ZNF684 | c.216G>A p.A72= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as COSV65519631; called by muse, mutect2, varscan2
- AATK | c.189+1103T>G | Intron (SNP) | VAF 32/208 reads (15%) | called by muse, mutect2, varscan2
- ADARB2 | c.1683-121C>A | Intron (SNP) | VAF 18/360 reads (5%) | called by muse, mutect2
- ALOX12B | c.*32C>G | 3'UTR (SNP) | VAF 15/402 reads (4%) | called by muse, mutect2
- AMER1 | c.*3742C>A | 3'UTR (SNP) | VAF 47/386 reads (12%) | called by muse, mutect2, varscan2
- APEX1 | c.-10C>A | 5'UTR (SNP) | VAF 23/803 reads (3%) | called by muse, mutect2
- ARIH2 | chr3:48918552 C>G | 5'Flank (SNP) | VAF 20/704 reads (3%) | called by muse, mutect2
- ATP6V0E2 | c.-3G>T | 5'UTR (SNP) | VAF 20/641 reads (3%) | catalogued as rs1250136609; called by muse, mutect2
- AUTS2 | c.661-145298G>T | Intron (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- BLACE | n.1336C>A | RNA (SNP) | VAF 13/373 reads (3%) | catalogued as rs1341574462; called by muse, mutect2
- C22orf15 | c.-47G>C | 5'UTR (SNP) | VAF 59/481 reads (12%) | called by muse, mutect2, varscan2
- CHRAC1 | c.147+312G>A | Intron (SNP) | VAF 105/499 reads (21%) | called by muse, mutect2, varscan2
- COG5 | c.-29C>G | 5'UTR (SNP) | VAF 109/1160 reads (9%) | catalogued as COSV51742928; called by muse, mutect2
- CRYAB | c.325-260C>G | Intron (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- EFCAB5 | c.2738-4508T>A | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- ELP4 | c.1146+31784T>C | Intron (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- EYS | c.1767-7349G>C | Intron (SNP) | VAF 27/318 reads (8%) | called by muse, varscan2
- FMR1 | c.-89G>T | 5'UTR (SNP) | VAF 11/76 reads (14%) | catalogued as rs1327958917; called by muse, mutect2, varscan2
- G6PD | c.771-28G>T | Intron (SNP) | VAF 35/325 reads (11%) | catalogued as rs1557230089; called by muse, varscan2
- GLTPP1 | n.150C>A | RNA (SNP) | VAF 123/1187 reads (10%) | called by muse, mutect2, varscan2
- ICOS | c.-28C>G | 5'UTR (SNP) | VAF 15/121 reads (12%) | catalogued as COSV100320460; called by muse, mutect2, varscan2
- KCNMB2 | c.57-998G>A | Intron (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- LY6K | c.218-160G>A | Intron (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- NANOS3 | chr19:13874769 C>A | 5'Flank (SNP) | VAF 41/432 reads (9%) | catalogued as rs757723823; called by muse, mutect2
- OR3A4P | n.1363T>C | RNA (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2
- OR5E1P | n.486G>A | RNA (SNP) | VAF 9/235 reads (4%) | called by muse, mutect2
- PAPOLA | c.-189C>A | 5'UTR (SNP) | VAF 45/241 reads (19%) | called by muse, mutect2, varscan2
- PHC1 | c.*428G>C | 3'UTR (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65808C>T | Intron (SNP) | VAF 62/480 reads (13%) | catalogued as rs558170028, COSV58240710; called by muse, mutect2, varscan2
- SERPINA13P | n.102T>C | RNA (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2, varscan2
- SFR1 | chr10:104122113 G>T | 5'Flank (SNP) | VAF 28/262 reads (11%) | catalogued as rs550363135; called by muse, mutect2, varscan2
- SIRPB1 | c.76+16040G>C | Intron (SNP) | VAF 18/218 reads (8%) | catalogued as rs1568699490; called by muse, mutect2
- SNORD115-23 | n.9G>A | RNA (SNP) | VAF 42/351 reads (12%) | called by muse, mutect2, varscan2
- SNORD116-10 | n.6G>A | RNA (SNP) | VAF 3/30 reads (10%) | catalogued as rs1180155711; called by muse, mutect2
- TBC1D3P1 | n.349A>G | RNA (SNP) | VAF 120/926 reads (13%) | called by muse, mutect2, varscan2
- TPCN1 | chr12:113221260 G>A | 5'Flank (SNP) | VAF 33/291 reads (11%) | called by muse, mutect2, varscan2
- TRIM27 | c.946+17A>C | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- UBTFL2 | n.456T>C | RNA (SNP) | VAF 28/310 reads (9%) | called by muse, mutect2
- ZBP1 | c.1094-2393T>G | Intron (SNP) | VAF 8/77 reads (10%) | catalogued as rs1332033555; called by muse, mutect2, varscan2
